Gene-level copy-number profile of tumor specimen TCGA-BG-A3PP-01A from TCGA case TCGA-BG-A3PP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 82.8 years (30,227 days).
Specimen TCGA-BG-A3PP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.6a35ca87-4e02-4b4b-8969-cf0b39d4f883.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BG-A3PP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fde03b3e-a88b-426f-bd25-976b4f0f49a6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 13,162; copy number 3: 14,852; copy number 4: 23,514; copy number 5: 2,462; copy number 6: 2,223; copy number 7: 2,648; copy number 8: 96; copy number 9: 185; copy number 10: 305; copy number 11: 61; copy number 12: 128; copy number 13: 65; copy number 14: 25; copy number 15: 3; copy number 16: 29; copy number 17: 19; copy number 21: 13; copy number 26: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BG-A3PP-01A-11D-A227-01): tumor purity 0.59, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 857 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:217,978,707–219,070,022, 55 genes, copy number 9: TNS1-AS1, RUFY4, CXCR2P1, CXCR2, CXCR1, HMGB1P9, ARPC2, AC021016.1, GPBAR1, AAMP, PNKD, TMBIM1, MIR6513, CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P, PLCD4, ZNF142, BCS1L, RNF25, STK36, TTLL4, CYP27A1, AC009974.2, AC009974.1, PRKAG3, MIR9500, RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1, CFAP65, IHH, MIR3131, AC097468.3.
- chr3:146,571,477–147,370,656, 6 genes, copy number 10 (within-gene range 6–10): RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P.
- chr3:167,065,831–169,038,416, 26 genes, copy number 9: PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr3:171,459,248–186,493,661, 259 genes, copy number 10–13 (broad region; genes not listed).
- chr8:41,645,177–56,656,496, 233 genes, copy number 10–12 (broad region; genes not listed).
- chr8:121,639,293–121,994,185, 1 gene, copy number 15 (within-gene range 2–15): HAS2-AS1.
- chr8:128,323,131–128,564,679, 2 genes, copy number 15 (within-gene range 2–15): AC100822.1, LINC00824.
- chr10:45,678,692–46,330,207, 18 genes, copy number 11: AGAP10P, FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL.
- chr10:61,406,642–64,693,446, 36 genes, copy number 9–16 (within-gene range 2–16): TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3, AC022387.2, MRPL35P2, AC022387.1, AC013287.1, RPL7AP50, AC012558.1, DBF4P1.
- chr10:75,210,154–76,560,168, 19 genes, copy number 26 (within-gene range 2–26): VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr11:33,774,699–33,892,076, 8 genes, copy number 9: FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1.
- chr11:63,681,446–65,058,553, 82 genes, copy number 9 (broad region; genes not listed).
- chr11:72,836,745–74,311,640, 43 genes, copy number 11 (within-gene range 5–11): FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1.
- chr11:76,349,956–77,994,671, 43 genes, copy number 14–26 (within-gene range 2–26): THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4.
- chr17:27,746,132–27,991,787, 7 genes, copy number 9 (within-gene range 5–9): LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3.
- chr19:9,087,061–9,351,162, 19 genes, copy number 17 (within-gene range 2–17): OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P, OR7E24, OR7E18P, OR7E19P, OR7H1P, ZNF699, AC011451.1, ZNF559.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
